TCGA case TCGA-EE-A29C — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: University of Sydney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fc5b5d2f-0d03-45c2-b7a0-ba6ec108fe51

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 20 years; Vital status: Dead; Days to death: 2,402 days (6.6 years).

Diagnoses (7)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.5; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Classification of tumor: Progression; Age at diagnosis: 21.4 years (7,810 days); Days to diagnosis: 300 days; Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Trunk; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >1.0-2.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 20.6 years (7,510 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 369 days (1.0 years); Days to treatment end: 371 days (1.0 years); Treatment dose: 7 Gy; Number of fractions: 3; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Days to treatment start: 439 days (1.2 years); Days to treatment end: 620 days (1.7 years); Clinical trial indicator: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: BRAF Inhibitor; Days to treatment start: 1,114 days (3.0 years); Days to treatment end: 1,502 days (4.1 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Ipilimumab; Days to treatment start: 1,500 days (4.1 years); Days to treatment end: 1,623 days (4.4 years); Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Dabrafenib + Trametinib; Days to treatment start: 2,262 days (6.2 years); Days to treatment end: 2,413 days (6.6 years); Treatment outcome: Progressive Disease.
4. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lymph node, NOS. Age at diagnosis: 21.1 years (7,714 days); Days to diagnosis: 204 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 221 days.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.
5. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lymph node, NOS. Age at diagnosis: 21.5 years (7,837 days); Days to diagnosis: 327 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 336 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.
6. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lung, NOS. Age at diagnosis: 21.7 years (7,914 days); Days to diagnosis: 404 days (1.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.
7. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Lymph node, NOS. Age at diagnosis: 26.6 years (9,722 days); Days to diagnosis: 2,212 days (6.1 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Surgery, NOS, for progressive disease.

Follow-up (6 entries)
- Day 204 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 204 days.
- Day 327 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 327 days.
- Day 404 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 404 days (1.1 years).
- Days to follow up: 1,455 days (4.0 years); Disease response: With Tumor.
- Day 2,212 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 2,212 days (6.1 years).
- Days to follow up: 2,402 days (6.6 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 4.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EE-A29C-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EE-A29C-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-EE-A29C-06A-02-TSB: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-EE-A29C-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 1.7; Primary melanoma tumor ulceration: No; Primary melanoma mitotic rate: 4; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Subsequent known primaries: No.
- Drug treatment 2: Pharmaceutical therapy drug name: GSK Braf Inhibitor; Treatment best response: Clinical Progressive Disease.
- Drug treatment 3: Pharmaceutical therapy drug name: Yervoy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,402 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,402 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 204 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EE-A29C-06A-21D-A191-01): tumor purity 0.62, ploidy 1.72, whole-genome doublings 0.
